Somatic mutation profile of tumor specimen TARGET-30-PASUYG-01A (aliquot TARGET-30-PASUYG-01A-01D) from TARGET case TARGET-30-PASUYG, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 3.9 years (1,418 days).
Specimen TARGET-30-PASUYG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 14e8aead-375d-4dd8-9001-392a24523ce4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PASUYG-10A (Blood Derived Normal), aliquot TARGET-30-PASUYG-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2815e94f-42aa-403b-a1e0-26a4dd1c8156

The open-access MAF lists 28 somatic variants for this specimen: 24 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 3, Nonsense Mutation 1, Frame Shift Del 1, Splice Region 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARPP21 | c.2137del p.V713Cfs*4 | Frame Shift Del (DEL) | VAF 54/119 reads (45%) | catalogued as COSV51798752; called by mutect2, pindel, varscan2
- CASP1 | c.453G>A p.E151= (on ENST00000436863 / NM_033292.4; = p.E130= on NM_001223.5 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 3/26 reads (12%) | catalogued as COSV62056134; called by muse, mutect2
- CR2 | c.1321C>A p.P441T | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.967); catalogued as COSV65506536; called by muse, mutect2, varscan2
- DLX5 | c.681G>T p.Q227H | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV56032022; called by muse, mutect2, varscan2
- FAT2 | c.191A>T p.E64V | Missense Mutation (SNP) | VAF 26/207 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV55815914; called by muse, mutect2, varscan2
- GPT | c.162G>C p.Q54H | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.764); catalogued as COSV52952610; called by muse, mutect2, varscan2
- GSTA1 | c.660C>A p.F220L | Missense Mutation (SNP) | VAF 5/99 reads (5%) | SIFT tolerated (0.23); PolyPhen benign (0.073); catalogued as COSV58016484; called by muse, mutect2
- MEN1 | c.1681G>A p.E561K | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.425); catalogued as CM050662; called by muse, mutect2, varscan2
- MPZL3 | c.41T>C p.L14P | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.564); catalogued as COSV54048468; called by muse, mutect2, varscan2
- MYO10 | c.5894G>T p.G1965V | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs527910551, COSV57018616; called by muse, mutect2, varscan2
- OR14I1 | c.694C>T p.R232* | Nonsense Mutation (SNP) | VAF 17/138 reads (12%) | catalogued as rs374606822, COSV61198982; called by muse, mutect2, varscan2
- PIGO | c.2908C>T p.R970W | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.405); catalogued as rs748546962, COSV53052830; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RRM1 | c.2074C>T p.L692F | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.145); catalogued as COSV56163670; called by muse, mutect2, varscan2
- STAB2 | c.5908T>C p.C1970R | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1424266175, COSV66336489; called by muse, mutect2, varscan2
- ANAPC5 | c.1495C>A p.P499T | Missense Mutation (SNP) | VAF 30/396 reads (8%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.946); called by muse, mutect2
- CASR | c.1794G>C p.W598C (on ENST00000490131; = p.W675C on NM_000388.4) | Missense Mutation (SNP) | VAF 12/133 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- DGKD | c.1516G>A p.V506M (on ENST00000264057 / NM_152879.3; = p.V462M on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.781); called by muse, mutect2
- ENO3 | c.247A>G p.S83G | Missense Mutation (SNP) | VAF 18/252 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.115); called by muse, mutect2
- GUCY2C | c.1945C>G p.P649A | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MAN2A1 | c.633T>A p.F211L | Missense Mutation (SNP) | VAF 8/97 reads (8%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.896); called by muse, mutect2
- NPEPPS | c.2311G>T p.D771Y | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); called by mutect2, varscan2
- OR2T1 | c.616C>A p.L206M | Missense Mutation (SNP) | VAF 6/109 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- OSBPL3 | c.551G>T p.R184L | Missense Mutation (SNP) | VAF 8/103 reads (8%) | SIFT tolerated (0.39); PolyPhen benign (0.049); called by muse, mutect2
- PATE2 | c.248G>C p.S83T | Missense Mutation (SNP) | VAF 4/51 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2
- DBF4 | c.1395C>T p.S465= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as rs377207959, COSV55995777, COSV55996273; called by muse, mutect2, varscan2
- PVR | c.90C>G p.V30= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as COSV51822489; called by muse, mutect2, varscan2
- SLC35B1 | c.600G>T p.G200= (on ENST00000649906; = p.G163= on NM_005827.4) | Silent (SNP) | VAF 10/254 reads (4%) | called by muse, mutect2
- BCL2L14 | c.679-104T>C | Intron (SNP) | VAF 8/70 reads (11%) | called by muse, mutect2, varscan2
